Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3544, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3544-01A (Primary Tumor).

Diagnosis:

Resected colon with a moderately differentiated adenocarcinoma of colorectal type, measuring 2.5 cm in diameter, with infiltration of the tunica muscularis propria. Tumor-free lymph nodes in the region. Tumor-free colon resection margins.

Tumor stage therefore pT2 pN0 (0/21) pMX; G2, L0, V0, R local 0.

Source: NCI Genomic Data Commons file fc256406-a519-4a84-9c1a-09b8f3f3ee10 (TCGA-AA-3544.93EA637F-9CCB-4B49-BC45-E7E5388143F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).